Gene-level copy-number profile of tumor specimen TCGA-69-A59K-01A from TCGA case TCGA-69-A59K, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 60.5 years (22,093 days).
Specimen TCGA-69-A59K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.4c8d5940-1681-4bad-89b1-aa8853507679.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-69-A59K-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/3dd3eb09-0a41-45e3-9ea4-a04d8c787cb1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 1,683; copy number 2: 18,536; copy number 3: 10,357; copy number 4: 21,547; copy number 5: 4,605; copy number 6: 669; copy number 7: 693; copy number 8: 576; copy number 9: 777; copy number 11: 171; copy number 12: 192.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:93,309,669–93,395,855, 2 genes: AL160159.1, HNRNPA1P29.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,140 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:127,215,127–159,233,377, 769 genes, copy number 9 (broad region; genes not listed).
- chr16:29,816,152–31,165,927, 130 genes, copy number 12 (within-gene range 3–12) (broad region; genes not listed).
- chr17:38,530,031–41,350,828, 171 genes, copy number 11 (broad region; genes not listed).
- chr19:32,345,594–34,471,251, 62 genes, copy number 12 (within-gene range 7–12) (broad region; genes not listed).
- chr20:42,072,752–43,231,260, 8 genes, copy number 9 (within-gene range 4–9): PTPRT, AL035666.1, AL031656.1, PTPRT-AS1, RN7SKP100, AL021395.1, RN7SL666P, PPIAP21.

Autosomal genes at a single copy (total copy number 1): 1,683. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
